Somatic mutation profile of tumor specimen 1563ef63-d2e6-406f-adc1-255949 (aliquot 1563ef63-d2e6-406f-adc1-255949_D6) from CPTAC case 11CO037, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB.
Specimen 1563ef63-d2e6-406f-adc1-255949: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2eadc499-9999-4231-bf82-6dd924b539c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 38fe94db-051d-408f-abe8-7e87c2 (Blood Derived Normal), aliquot 38fe94db-051d-408f-abe8-7e87c2_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b23cdaf2-7587-4019-9c3e-4b91d175f5c7

The open-access MAF lists 114 somatic variants for this specimen: 80 protein-altering or splice-affecting, 27 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 27, Nonsense Mutation 6, Intron 3, Splice Region 3, 5'UTR 3, Splice Site 2, RNA 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.376T>G p.Y126D | Missense Mutation (SNP) | VAF 50/130 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs886039483, CM118879, COSV52661802, COSV52809424, COSV53031989, COSV53515469; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADAM21 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 71/470 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs775142915, COSV50791693; called by muse, mutect2, varscan2
- ADCY10 | c.3074G>A p.R1025H | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.042); catalogued as rs764592790, COSV63243801; called by muse, mutect2, varscan2
- C5AR1 | c.650C>T p.T217M | Missense Mutation (SNP) | VAF 60/152 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); catalogued as rs200119585, COSV61892828, COSV61893040; called by muse, mutect2, varscan2
- CCDC38 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as rs1276692335; called by muse, mutect2, varscan2
- CFHR4 | c.1631C>A p.T544N (on ENST00000367416 / NM_001201551.2; = p.T298N on NM_006684.5) | Missense Mutation (SNP) | VAF 31/199 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as rs767076488; called by muse, mutect2, varscan2
- CMYA5 | c.10610C>T p.T3537M | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs575546411, COSV71405397; called by muse, mutect2, varscan2
- COLQ | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 33/191 reads (17%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.903); catalogued as rs201158622, COSV67524892, COSV67525091; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAJC10 | c.1911dup p.P638Sfs*6 | Frame Shift Ins (INS) | VAF 9/50 reads (18%) | catalogued as rs1283431287; called by mutect2, pindel, varscan2
- GP6 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 142/315 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs777656189, COSV59977392; called by muse, mutect2, varscan2
- HCN1 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV100299660; called by muse, mutect2, varscan2
- HOGA1 | c.363G>A p.M121I | Missense Mutation (SNP) | VAF 111/368 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV65706808; called by muse, mutect2, varscan2
- IRAK1 | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 36/302 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as rs1557129236; called by muse, mutect2, varscan2
- IRS4 | c.1301G>A p.R434H | Missense Mutation (SNP) | VAF 65/548 reads (12%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as COSV64534247; called by muse, mutect2, varscan2
- LCLAT1 | c.505A>G p.I169V | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.028); catalogued as rs750575432; called by muse, mutect2
- LY6E | c.49C>T p.R17* | Nonsense Mutation (SNP) | VAF 26/208 reads (13%) | catalogued as rs1563909565, COSV52869946; called by muse, mutect2, varscan2
- MYCL | c.388G>T p.D130Y (on ENST00000372816 / NM_001033081.3; = p.D160Y on NM_005376.5) | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV100862313, COSV100862338; called by muse, mutect2, varscan2
- NDUFA3 | c.146C>T p.T49M | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.832); catalogued as rs769564432, COSV52927479; called by muse, mutect2, varscan2
- NEUROD1 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 52/506 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54548947, COSV99717089; called by muse, mutect2
- OR2T12 | c.489C>A p.S163R | Missense Mutation (SNP) | VAF 180/676 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.33); catalogued as COSV100528023; called by muse, varscan2
- OR4K2 | c.259A>C p.T87P | Missense Mutation (SNP) | VAF 39/271 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.078); catalogued as COSV100064191, COSV53850359; called by muse, mutect2, varscan2
- PATJ | c.5149C>G p.R1717G | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs146406799; called by muse, varscan2
- PCDHB11 | c.2129C>T p.A710V | Missense Mutation (SNP) | VAF 131/477 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs781883051, COSV61309842; called by muse, mutect2, varscan2
- PDCD7 | c.1173G>T p.K391N | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs756364218, COSV52599860; called by muse, mutect2, varscan2
- PDE4DIP | c.2746C>T p.R916W | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782015690, COSV100518735; called by muse, mutect2, varscan2
- PHLDB2 | c.1540C>T p.L514F | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0.046); catalogued as rs752258063; called by muse, mutect2, varscan2
- PRDM16 | c.3044G>A p.R1015H | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758654133, COSV99576663; called by muse, mutect2, varscan2
- RPGRIP1 | c.1687C>T p.R563* | Nonsense Mutation (SNP) | VAF 25/84 reads (30%) | catalogued as rs776963292, COSV52847067; called by muse, mutect2, varscan2
- RPL22L1 | c.203C>G p.S68C | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.429); catalogued as rs1027172577; called by muse, mutect2
- SALL1 | c.2330A>T p.N777I | Missense Mutation (SNP) | VAF 24/479 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51754884; called by muse, mutect2
- SAMD15 | c.1843C>T p.R615C | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs149116567; called by muse, mutect2, varscan2
- SCART1 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 29/178 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.222); catalogued as rs899652215; called by muse, mutect2, varscan2
- SLC12A5 | c.1328G>A p.R443H (on ENST00000454036 / NM_001134771.2; = p.R420H on NM_020708.5) | Missense Mutation (SNP) | VAF 84/265 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs757586510, COSV54794717; called by muse, mutect2, varscan2
- SLC2A3 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.077); catalogued as rs1197154662; called by muse, varscan2
- SLC4A3 | c.1906C>T p.R636W | Missense Mutation (SNP) | VAF 35/324 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs149889867; called by muse, mutect2, varscan2
- SOX11 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.098); catalogued as COSV58988152; called by muse, mutect2
- TACC1 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs368667882; called by muse, mutect2, varscan2
- TCF4 | c.1766G>A p.R589H | Missense Mutation (SNP) | VAF 71/400 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as rs1041108937; called by muse, mutect2, varscan2
- TP73 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.089); catalogued as rs748133630; called by muse, mutect2, varscan2
- TSPAN3 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51214771; called by muse, mutect2, varscan2
- UNC13A | c.2222G>A p.R741H | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1373427619; called by muse, mutect2, varscan2
- ADAM29 | c.1089A>G p.I363M | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); called by muse, mutect2
- ADGRG2 | c.2528G>A p.G843E (on ENST00000379869 / NM_001079858.3; = p.G840E on NM_005756.4) | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRG4 | c.889A>C p.M297L | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANO3 | c.2603G>A p.S868N | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- APPL2 | c.1109T>C p.I370T | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- BTBD1 | c.1084G>A p.V362I | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.061); called by muse, varscan2
- CDK1 | c.56A>G p.Y19C | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP41 | c.33G>A p.E11= | Splice Region (SNP) | VAF 18/358 reads (5%) | called by muse, mutect2
- CFAP43 | c.895+2T>C p.X299_splice | Splice Site (SNP) | VAF 15/47 reads (32%) | called by muse, mutect2, varscan2
- CYP7A1 | c.387C>A p.F129L | Missense Mutation (SNP) | VAF 22/255 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by muse, mutect2
- DGKQ | c.2621G>A p.G874D | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DYNC1H1 | c.4867C>T p.R1623W | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EDNRB | c.20T>C p.L7P | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- FBXL15 | c.395T>C p.L132P | Missense Mutation (SNP) | VAF 38/269 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GNAT3 | c.245T>C p.L82P | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV3-11 | c.305A>G p.D102G | Missense Mutation (SNP) | VAF 23/337 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNA6 | c.824C>A p.T275N | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- KERA | c.309C>A p.N103K | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); called by muse, mutect2
- KIAA1614 | c.998-1G>A p.X333_splice | Splice Site (SNP) | VAF 27/177 reads (15%) | called by muse, mutect2, varscan2
- LMNTD1 | c.200C>A p.T67N | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- MEN1 | c.1786A>G p.K596E | Missense Mutation (SNP) | VAF 55/400 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- MROH9 | c.845T>A p.F282Y | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- NFKBID | c.458del p.G153Afs*26 (on ENST00000396901; = p.G305Afs*26 on NM_032721.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 52/147 reads (35%) | called by mutect2, pindel, varscan2
- NHS | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NIBAN1 | c.2209G>T p.E737* | Nonsense Mutation (SNP) | VAF 24/179 reads (13%) | called by muse, mutect2, varscan2
- OXR1 | c.2111T>C p.F704S (on ENST00000442977 / NM_001198532.1; = p.F676S on NM_018002.3) | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ROCK2 | c.44A>G p.E15G | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPL10 | c.346C>T p.R116* | Nonsense Mutation (SNP) | VAF 88/556 reads (16%) | called by muse, mutect2, varscan2
- S1PR1 | c.95C>T p.T32M | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SNTG1 | c.969G>A p.V323= | Splice Region (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- STC1 | c.465C>A p.F155L | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- TBX22 | c.356+5G>T | Splice Region (SNP) | VAF 20/382 reads (5%) | called by muse, mutect2
- THSD7A | c.1881T>A p.C627* | Nonsense Mutation (SNP) | VAF 21/157 reads (13%) | called by muse, mutect2, varscan2
- TRIM23 | c.361G>T p.G121* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
- TSHZ3 | c.1336C>T p.P446S | Missense Mutation (SNP) | VAF 18/396 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.831); called by muse, mutect2
- UBR4 | c.10408G>A p.D3470N | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- WBP11 | c.999G>A p.M333I | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- ZBTB18 | c.121G>A p.V41I | Missense Mutation (SNP) | VAF 87/269 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ZZZ3 | c.1106C>T p.S369L | Missense Mutation (SNP) | VAF 25/205 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- AP2A1 | c.1965G>A p.S655= | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as rs1274742516; called by muse, mutect2
- APOA4 | c.444G>A p.T148= | Silent (SNP) | VAF 56/273 reads (21%) | catalogued as rs762145587; called by muse, mutect2, varscan2
- C2orf81 | c.567G>A p.P189= | Silent (SNP) | VAF 15/159 reads (9%) | called by muse, mutect2, varscan2
- CABLES1 | c.1299C>G p.L433= (on ENST00000256925 / NM_001100619.2; = p.L168= on NM_138375.2) | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as COSV99908473; called by muse, mutect2
- CEP126 | c.2757G>A p.P919= | Silent (SNP) | VAF 10/111 reads (9%) | catalogued as rs761348506, COSV54824879; called by muse, mutect2, varscan2
- CNGB3 | c.1332G>T p.V444= | Silent (SNP) | VAF 14/419 reads (3%) | catalogued as COSV60685299; called by muse, mutect2
- COL6A3 | c.7191C>T p.P2397= | Silent (SNP) | VAF 23/137 reads (17%) | catalogued as rs780105850, COSV55101643; called by muse, mutect2, varscan2
- CYSLTR2 | c.390C>T p.T130= | Silent (SNP) | VAF 76/362 reads (21%) | catalogued as rs953621282; called by muse, mutect2, varscan2
- DPP6 | c.2484C>T p.S828= (on ENST00000377770 / NM_001364500.2; = p.S766= on NM_001936.5) | Silent (SNP) | VAF 23/178 reads (13%) | catalogued as rs745973845; called by muse, mutect2, varscan2
- ELOVL1 | c.828C>G p.V276= | Silent (SNP) | VAF 79/288 reads (27%) | catalogued as rs1288480264; called by muse, mutect2, varscan2
- FBXO40 | c.1084C>A p.R362= | Silent (SNP) | VAF 71/319 reads (22%) | catalogued as COSV57523186; called by muse, mutect2, varscan2
- FGF14 | c.345C>T p.A115= | Silent (SNP) | VAF 28/311 reads (9%) | called by muse, mutect2
- GPRASP1 | c.2253C>A p.S751= | Silent (SNP) | VAF 33/210 reads (16%) | called by muse, mutect2, varscan2
- HK1 | c.978G>A p.P326= | Silent (SNP) | VAF 56/341 reads (16%) | catalogued as rs150869156; called by muse, mutect2, varscan2
- KALRN | c.6879C>T p.T2293= (on ENST00000360013 / NM_001024660.4; = p.T596= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/275 reads (13%) | catalogued as rs1216619193; called by muse, mutect2, varscan2
- LAMB4 | c.2970G>A p.E990= | Silent (SNP) | VAF 99/368 reads (27%) | catalogued as COSV52717377; called by muse, mutect2, varscan2
- MKNK2 | c.447C>T p.F149= | Silent (SNP) | VAF 6/113 reads (5%) | catalogued as rs951141429, COSV51734052; called by muse, mutect2
- MYO1C | c.609T>C p.D203= (on ENST00000648651 / NM_001080779.2; = p.D168= on NM_033375.5) | Silent (SNP) | VAF 160/410 reads (39%) | called by muse, varscan2
- OR52L1 | c.900C>A p.L300= | Silent (SNP) | VAF 11/228 reads (5%) | called by muse, mutect2
- PAIP1 | c.1194T>C p.F398= | Silent (SNP) | VAF 10/78 reads (13%) | called by muse, mutect2, varscan2
- PCDHB16 | c.441T>C p.P147= | Silent (SNP) | VAF 43/232 reads (19%) | called by muse, mutect2, varscan2
- PIWIL1 | c.42C>T p.R14= | Silent (SNP) | VAF 38/112 reads (34%) | catalogued as rs766374504, COSV99806109; called by muse, mutect2, varscan2
- RTP1 | c.378C>T p.R126= | Silent (SNP) | VAF 20/233 reads (9%) | catalogued as rs750359975, COSV56619041; called by muse, mutect2
- SLC6A19 | c.969C>T p.S323= | Silent (SNP) | VAF 77/574 reads (13%) | catalogued as rs763663833; called by muse, varscan2
- SOX8 | c.645C>T p.G215= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as rs1233756455; called by muse, mutect2, varscan2
- VEGFC | c.1077C>G p.A359= | Silent (SNP) | VAF 34/164 reads (21%) | catalogued as COSV54597984; called by muse, mutect2, varscan2
- ZKSCAN5 | c.465A>T p.A155= | Silent (SNP) | VAF 18/75 reads (24%) | called by muse, mutect2, varscan2
- ABHD4 | c.23+40C>T | Intron (SNP) | VAF 25/189 reads (13%) | called by muse, mutect2, varscan2
- AHRR | c.245-8776G>A | Intron (SNP) | VAF 14/87 reads (16%) | catalogued as rs1476717214, COSV100326681; called by muse, mutect2, varscan2
- CHODL | c.-58G>A | 5'UTR (SNP) | VAF 23/64 reads (36%) | catalogued as rs954892236; called by muse, mutect2, varscan2
- DMD | c.-24G>A | 5'UTR (SNP) | VAF 21/179 reads (12%) | called by muse, mutect2, varscan2
- OR2L1P | n.673G>A | RNA (SNP) | VAF 53/291 reads (18%) | catalogued as rs1211383701; called by muse, mutect2, varscan2
- PQBP1 | c.-224C>T | 5'UTR (SNP) | VAF 20/164 reads (12%) | catalogued as COSV99504087; called by muse, mutect2, varscan2
- TNPO2 | c.-13-243G>C | Intron (SNP) | VAF 3/23 reads (13%) | catalogued as rs1275333604; called by muse, mutect2
